Somatic mutation profile of tumor specimen 0DDKF7 from CCDI case PBBNMC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (434 days).
Specimen 0DDKF7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5446e1de-6b9b-42d1-9d70-fb9fac45f7f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDKF8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c350fb8c-3216-4ea6-85d5-d5188cf3160c

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RNF123 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 44/680 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1179415279; called by muse, mutect2
- SMARCB1 | c.1010del p.P337Rfs*100 (on ENST00000263121; = p.P383Rfs*100 on NM_003073.5) | Frame Shift Del (DEL) | VAF 287/473 reads (61%) | catalogued as COSV51955921; called by mutect2, pindel, varscan2
- EGF | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 33/651 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTBP1 | c.-29C>G | 5'UTR (SNP) | VAF 32/332 reads (10%) | catalogued as rs762757525; called by muse, varscan2
- UAP1L1 | c.1037+22C>T | Intron (SNP) | VAF 72/652 reads (11%) | called by muse, mutect2, varscan2
